Somatic mutation profile of tumor specimen TCGA-59-A5PD-01A (aliquot TCGA-59-A5PD-01A-11D-A403-09) from TCGA case TCGA-59-A5PD, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IC; Tumor grade: G3; Age at diagnosis: 55.5 years (20,263 days).
Specimen TCGA-59-A5PD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9b5db564-ed9b-484f-9570-9fc9e5081aec.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-59-A5PD-10A (Blood Derived Normal), aliquot TCGA-59-A5PD-10A-01D-A403-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6bcdf6af-8a83-4673-895c-6c6aaa0fc1e7

The open-access MAF lists 159 somatic variants for this specimen: 120 protein-altering or splice-affecting, 35 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 102, Silent 35, Nonsense Mutation 10, In Frame Del 4, Intron 2, Splice Site 2, 5'Flank 1, Nonstop Mutation 1, Frame Shift Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.438G>A p.W146* | Nonsense Mutation (SNP) | VAF 11/14 reads (79%) | hotspot (GDC flag); catalogued as rs1131691026, CM101750, COSV52661500, COSV52987374, COSV53571745; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACTN3 | c.1591C>T p.R531W | Missense Mutation (SNP) | VAF 39/67 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs749033120, COSV100074441; called by muse, mutect2, varscan2
- ADCY3 | c.1633T>C p.S545P | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV99568895; called by muse, mutect2, varscan2
- ADGRA1 | c.84G>T p.M28I | Missense Mutation (SNP) | VAF 6/93 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as rs1415478037, COSV101192817; called by muse, mutect2
- AFF2 | c.2518G>C p.A840P | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.99); PolyPhen benign (0.003); catalogued as COSV99665569; called by muse, mutect2, varscan2
- ANKRD33 | c.440A>G p.Q147R (on ENST00000340970 / NM_001304459.2; = p.Q272R on NM_182608.4) | Missense Mutation (SNP) | VAF 23/32 reads (72%) | SIFT tolerated (0.1); PolyPhen benign (0.164); catalogued as rs932643266, COSV100001461; called by mutect2, varscan2
- ANO7 | c.674C>G p.P225R (on ENST00000274979; = p.P171R on NM_001370694.2) | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.6); PolyPhen benign (0.029); catalogued as COSV51473822, COSV99239088; called by muse, mutect2, varscan2
- ATXN2L | c.718G>A p.D240N | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.07); catalogued as COSV57377597; called by muse, mutect2, varscan2
- AXL | c.1282C>G p.P428A | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); catalogued as COSV99997007; called by muse, mutect2, varscan2
- BNC2 | c.2180A>T p.E727V | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV101034073, COSV66140902; called by muse, mutect2, varscan2
- CDH10 | c.2156A>C p.K719T | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.405); catalogued as COSV52592709; called by muse, mutect2, varscan2
- CELSR1 | c.3433G>C p.G1145R | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99419403; called by muse, mutect2, varscan2
- CEMIP | c.4029C>G p.H1343Q | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.56); PolyPhen benign (0.01); catalogued as COSV99587103; called by muse, mutect2, varscan2
- CLIC1 | c.30G>T p.L10F | Missense Mutation (SNP) | VAF 41/77 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.141); catalogued as COSV100994945; called by muse, mutect2, varscan2
- CMYA5 | c.9193C>T p.P3065S | Missense Mutation (SNP) | VAF 61/92 reads (66%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV101484258; called by muse, mutect2, varscan2
- CXorf66 | c.461A>C p.K154T | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.1); catalogued as COSV100983919; called by muse, mutect2, varscan2
- CYP4Z1 | c.250G>T p.V84F | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT tolerated (1); PolyPhen possibly damaging (0.889); catalogued as COSV100497856, COSV61964969; called by muse, mutect2, varscan2
- CYYR1 | c.152A>T p.Y51F | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV100177383; called by muse, mutect2, varscan2
- DAPK3 | c.980A>T p.K327M | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT tolerated (0.1); PolyPhen benign (0.059); catalogued as COSV100009841; called by muse, mutect2, varscan2
- DDHD1 | c.26G>C p.S9T (on ENST00000323669; = p.S240T on NM_030637.3) | Missense Mutation (SNP) | VAF 19/28 reads (68%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV100079866; called by muse, mutect2, varscan2
- DDR2 | c.1378T>C p.S460P | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV100906779; called by muse, mutect2, varscan2
- DDX56 | c.1207C>G p.L403V | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.56); PolyPhen benign (0.01); catalogued as COSV99346191; called by muse, mutect2, varscan2
- DHX58 | c.905C>T p.A302V | Missense Mutation (SNP) | VAF 31/53 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99288418; called by muse, mutect2, varscan2
- DIDO1 | c.2683G>A p.A895T | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as rs763169157, COSV99826664; called by muse, mutect2, varscan2
- DIMT1 | c.200C>A p.T67N | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as COSV99551176; called by muse, mutect2, varscan2
- DISP1 | c.920C>T p.S307L | Missense Mutation (SNP) | VAF 56/160 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99451780; called by muse, mutect2, varscan2
- DLG1 | c.779C>A p.T260K | Missense Mutation (SNP) | VAF 17/190 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV100015785; called by muse, mutect2
- DNAH1 | c.7976A>G p.N2659S | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.047); catalogued as rs368763870; called by muse, mutect2, varscan2
- DNHD1 | c.12631G>C p.V4211L | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV99600703; called by muse, mutect2, varscan2
- DOCK4 | c.1441C>T p.R481W | Missense Mutation (SNP) | VAF 46/100 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs764783981, COSV70326490; called by muse, mutect2, varscan2
- DOCK5 | c.5536G>A p.E1846K | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.025); catalogued as rs779369988; called by muse, mutect2
- DRICH1 | c.324A>C p.L108F | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.193); catalogued as COSV100497496; called by muse, varscan2
- DSEL | c.2789G>A p.R930Q | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs1002639657, COSV100025142; called by muse, mutect2, varscan2
- FANCD2 | c.3289C>T p.R1097* | Nonsense Mutation (SNP) | VAF 21/91 reads (23%) | catalogued as COSV99812056; called by muse, mutect2, varscan2
- FBXO38 | c.1622T>G p.L541* | Nonsense Mutation (SNP) | VAF 8/24 reads (33%) | catalogued as COSV99693798; called by muse, mutect2, varscan2
- FOXRED2 | c.1943G>A p.G648D | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.001); catalogued as COSV99341070; called by muse, mutect2, varscan2
- FRAS1 | c.11941G>A p.E3981K | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.011); catalogued as COSV99354729; called by muse, mutect2, varscan2
- FRMPD1 | c.4472G>A p.R1491H | Missense Mutation (SNP) | VAF 37/53 reads (70%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs780248862, COSV66703083; called by muse, mutect2, varscan2
- GDF7 | c.1051C>T p.R351C | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV55347445; called by muse, mutect2, varscan2
- GGT7 | c.1000G>C p.E334Q | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.502); catalogued as COSV100322130; called by muse, mutect2, varscan2
- GLDC | c.185A>T p.D62V | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.115); catalogued as COSV100394421; called by muse, mutect2, varscan2
- GLUD2 | c.1315T>A p.Y439N | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100047015; called by muse, mutect2, varscan2
- GUCA1C | c.125C>A p.T42K | Missense Mutation (SNP) | VAF 18/192 reads (9%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV99227221; called by muse, mutect2
- HAGHL | c.655G>C p.G219R | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.167); catalogued as COSV99285093; called by muse, mutect2
- HID1 | c.295C>G p.R99G | Missense Mutation (SNP) | VAF 124/154 reads (81%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV100586049; called by muse, mutect2, varscan2
- ICE1 | c.1695G>C p.K565N | Missense Mutation (SNP) | VAF 21/164 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); catalogued as COSV56820422, COSV99665345; called by muse, mutect2, varscan2
- ISY1-RAB43 | c.212G>T p.R71L | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99860938; called by muse, mutect2, varscan2
- KCNJ1 | c.85G>A p.V29I | Missense Mutation (SNP) | VAF 27/40 reads (68%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs773713405, COSV60662790; called by muse, mutect2, varscan2
- KIF5C | c.2715G>C p.K905N | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV101276184; called by muse, mutect2, varscan2
- KIR2DL1 | c.720C>A p.N240K | Missense Mutation (SNP) | VAF 54/227 reads (24%) | SIFT tolerated (0.96); PolyPhen benign (0.13); catalogued as rs1471595630, COSV52409218; called by muse, mutect2, varscan2
- KMT2C | c.2770-1G>T p.X924_splice | Splice Site (SNP) | VAF 36/92 reads (39%) | catalogued as COSV100074974; called by muse, mutect2, varscan2
- KNDC1 | c.154G>T p.E52* | Nonsense Mutation (SNP) | VAF 16/134 reads (12%) | catalogued as COSV100464899, COSV100465842; called by muse, varscan2
- KNDC1 | c.155A>T p.E52V | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100465848; called by muse, mutect2, varscan2
- KRBA2 | c.166T>G p.S56A | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.052); catalogued as COSV100497711; called by muse, mutect2, varscan2
- LCT | c.5452C>G p.P1818A | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.163); catalogued as COSV99739451; called by muse, mutect2, varscan2
- LIMCH1 | c.3217C>G p.R1073G | Missense Mutation (SNP) | VAF 70/112 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100574226, COSV58274086; called by muse, mutect2, varscan2
- LRBA | c.8274T>G p.Y2758* | Nonsense Mutation (SNP) | VAF 35/85 reads (41%) | catalogued as COSV100841966; called by muse, mutect2, varscan2
- LRFN2 | c.1531G>A p.A511T | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.009); catalogued as rs529101187, COSV57831526; called by muse, mutect2
- MACF1 | c.11845G>C p.V3949L (on ENST00000372915; = p.V1882L on NM_012090.5) | Missense Mutation (SNP) | VAF 10/44 reads (23%) | catalogued as COSV99246058; called by muse, mutect2, varscan2
- MFHAS1 | c.2960G>A p.C987Y | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99359801; called by muse, mutect2, varscan2
- MFSD6 | c.101A>G p.E34G | Missense Mutation (SNP) | VAF 30/164 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV99855319; called by muse, mutect2, varscan2
- MN1 | c.3455C>G p.P1152R | Missense Mutation (SNP) | VAF 14/14 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100180041, COSV100180115; called by muse, mutect2, varscan2
- MYF5 | c.311A>C p.E104A | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.332); catalogued as COSV99953365; called by muse, mutect2, varscan2
- MYO1E | c.675C>G p.H225Q | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99896313; called by muse, mutect2, varscan2
- NBAS | c.1105C>G p.P369A | Missense Mutation (SNP) | VAF 81/162 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV99871132; called by muse, mutect2
- NEBL | c.433C>A p.P145T | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.184); catalogued as COSV101008951; called by muse, mutect2, varscan2
- NKD2 | c.668G>C p.S223T | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.116); catalogued as COSV56893348; called by muse, mutect2
- OPN5 | c.347T>A p.F116Y | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99789975; called by muse, mutect2, varscan2
- ORM1 | c.540G>T p.K180N | Missense Mutation (SNP) | VAF 23/32 reads (72%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV99407648; called by muse, mutect2, varscan2
- PCDHA11 | c.146C>T p.A49V | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as rs1554162740, COSV56513343; called by muse, mutect2, varscan2
- PDZD8 | c.1609A>G p.I537V | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs115471338, COSV100559600; called by muse, mutect2, varscan2
- PFKM | c.1171G>T p.V391F | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.7); PolyPhen benign (0.125); catalogued as COSV100402644; called by muse, mutect2, varscan2
- PLA2G12A | c.55G>C p.V19L | Missense Mutation (SNP) | VAF 21/27 reads (78%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV99697372; called by muse, mutect2, varscan2
- POGK | c.1342G>C p.D448H | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.968); catalogued as COSV100902551; called by muse, mutect2, varscan2
- RANBP2 | c.4984T>C p.F1662L | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.141); catalogued as COSV99312864; called by mutect2, varscan2
- RAPGEF1 | c.1975G>C p.A659P | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.125); catalogued as COSV100940687; called by muse, mutect2, varscan2
- RHBDF2 | c.1540A>T p.K514* | Nonsense Mutation (SNP) | VAF 12/67 reads (18%) | catalogued as COSV99166252; called by muse, mutect2, varscan2
- RIF1 | c.1619C>G p.S540C | Missense Mutation (SNP) | VAF 120/339 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99690992; called by muse, mutect2, varscan2
- RTL9 | c.1330G>A p.V444I | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as COSV101511764; called by muse, mutect2, varscan2
- SAMD3 | c.403C>G p.L135V | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.005); catalogued as COSV100148360, COSV60775908; called by muse, mutect2, varscan2
- SCG3 | c.983T>C p.L328P | Missense Mutation (SNP) | VAF 13/142 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99591124; called by muse, mutect2
- SDK2 | c.4739G>C p.S1580T | Missense Mutation (SNP) | VAF 80/112 reads (71%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as COSV101168184; called by muse, mutect2, varscan2
- SELP | c.1282G>T p.V428F | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.747); catalogued as rs991241164, COSV99740697; called by muse, mutect2, varscan2
- SESN3 | c.271C>G p.R91G | Missense Mutation (SNP) | VAF 37/69 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53583899, COSV99565871; called by muse, mutect2, varscan2
- SHF | c.619T>C p.W207R | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99334679; called by muse, mutect2, varscan2
- SIGLEC12 | c.1654G>A p.A552T (on ENST00000291707 / NM_053003.4; = p.A434T on NM_033329.2) | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.24); PolyPhen benign (0.04); catalogued as rs1456926344, COSV99389514; called by muse, mutect2, varscan2
- SKIV2L | c.388A>G p.T130A | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV100952829; called by muse, mutect2, varscan2
- SLC16A5 | c.1453C>G p.L485V | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.171); catalogued as COSV99822710; called by muse, mutect2, varscan2
- SMC3 | c.788C>A p.A263E | Missense Mutation (SNP) | VAF 107/210 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV100700005, COSV62420395; called by muse, mutect2, varscan2
- SNX19 | c.1600C>G p.R534G | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs752088578, COSV99773192, COSV99773442; called by muse, mutect2, varscan2
- SPATA18 | c.554A>T p.H185L | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV99731012; called by muse, mutect2
- SSX7 | c.330G>T p.K110N | Missense Mutation (SNP) | VAF 66/539 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV99993971; called by mutect2, varscan2
- STAT4 | c.634G>T p.A212S | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV100636133, COSV61831894; called by muse, mutect2, varscan2
- TACC2 | c.1471G>T p.A491S | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.205); catalogued as COSV100553283; called by muse, mutect2, varscan2
- TFAP2B | c.945A>T p.E315D | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV99540652; called by muse, mutect2, varscan2
- TFE3 | c.1525C>G p.H509D | Missense Mutation (SNP) | VAF 56/66 reads (85%) | SIFT tolerated (0.58); PolyPhen benign (0.066); catalogued as COSV100252737; called by muse, mutect2, varscan2
- TMC5 | c.35A>G p.E12G | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.494); catalogued as COSV101196876; called by muse, mutect2, varscan2
- TMPRSS11F | c.1153T>C p.C385R | Missense Mutation (SNP) | VAF 36/156 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100678710; called by muse, mutect2, varscan2
- TRADD | c.85T>C p.S29P | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs943704865, COSV99263595; called by muse, mutect2, varscan2
- TRPV3 | c.710C>G p.A237G | Missense Mutation (SNP) | VAF 22/133 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.258); catalogued as COSV100028018; called by muse, mutect2, varscan2
- TTLL11 | c.1453A>T p.K485* | Nonsense Mutation (SNP) | VAF 60/80 reads (75%) | catalogued as COSV100389123; called by muse, mutect2, varscan2
- TTN | c.18520G>T p.D6174Y (on ENST00000591111; = p.D5247Y on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/25 reads (48%) | PolyPhen possibly damaging (0.714); catalogued as COSV100623573; called by muse, mutect2, varscan2
- TXNDC11 | c.1976C>G p.T659S (on ENST00000356957 / NM_001303447.2; = p.T632S on NM_015914.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.53); PolyPhen benign (0.057); catalogued as COSV99298210; called by muse, mutect2, varscan2
- UBN1 | c.844C>G p.L282V | Missense Mutation (SNP) | VAF 22/35 reads (63%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV99278434; called by muse, mutect2, varscan2
- UNC13B | c.1241A>T p.D414V | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101037090; called by mutect2, varscan2
- VWA5A | c.2224A>T p.K742* | Nonsense Mutation (SNP) | VAF 14/23 reads (61%) | catalogued as COSV100827935; called by muse, mutect2, varscan2
- XCR1 | c.937C>A p.P313T | Missense Mutation (SNP) | VAF 19/22 reads (86%) | SIFT tolerated (0.24); PolyPhen benign (0.027); catalogued as COSV100499440; called by muse, mutect2, varscan2
- ZBBX | c.1120G>A p.A374T | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.013); catalogued as COSV100284698; called by muse, mutect2, varscan2
- ZDHHC6 | c.694C>G p.L232V | Missense Mutation (SNP) | VAF 99/232 reads (43%) | SIFT tolerated (0.3); PolyPhen benign (0.228); catalogued as COSV101024442; called by muse, mutect2, varscan2
- ZNF280C | c.876G>A p.M292I | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100921260; called by muse, mutect2, varscan2
- ZNF804A | c.3156C>A p.Y1052* | Nonsense Mutation (SNP) | VAF 9/70 reads (13%) | catalogued as COSV100169414; called by muse, mutect2, varscan2
- ZSCAN2 | c.920A>C p.Q307P | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV100306940; called by muse, mutect2, varscan2
- CHID1 | c.538_546+23del p.X180_splice | Splice Site (DEL) | VAF 9/28 reads (32%) | called by mutect2, pindel
- EPHA5 | c.348_374del p.S116_S124del | In Frame Del (DEL) | VAF 33/131 reads (25%) | called by mutect2, pindel, varscan2
- OR8D4 | c.403_420del p.I135_V140del | In Frame Del (DEL) | VAF 9/20 reads (45%) | called by mutect2, varscan2
- PIK3AP1 | c.1882_1902del p.H628_L634del | In Frame Del (DEL) | VAF 10/26 reads (38%) | called by mutect2, pindel, varscan2
- RFX7 | c.3369_3378del p.Q1124Nfs*5 (on ENST00000559447 / NM_001368074.1; = p.Q1221Nfs*5 on NM_022841.7 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 11/56 reads (20%) | called by mutect2, pindel
- SECISBP2L | c.738_740del p.R249del | In Frame Del (DEL) | VAF 6/28 reads (21%) | called by mutect2, pindel
- SETX | c.2613_2614insTAGTTTAGAAT p.E872* | Nonsense Mutation (INS) | VAF 7/46 reads (15%) | called by mutect2, pindel, varscan2
- TAF1D | c.829_*14del | Nonstop Mutation (DEL) | VAF 35/87 reads (40%) | called by mutect2, pindel, varscan2
- AC008397.2 | c.1560G>C p.V520= | Silent (SNP) | VAF 28/82 reads (34%) | catalogued as COSV99442059; called by muse, mutect2, varscan2
- ANTXR1 | c.1578C>A p.P526= | Silent (SNP) | VAF 26/78 reads (33%) | catalogued as COSV100362882; called by muse, varscan2
- BOC | c.2592C>T p.S864= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV99849137; called by muse, mutect2, varscan2
- CCDC136 | c.72A>G p.E24= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV99922977; called by muse, mutect2, varscan2
- CHRM4 | c.1395G>A p.R465= | Silent (SNP) | VAF 19/38 reads (50%) | catalogued as COSV58995814; called by muse, mutect2, varscan2
- COL12A1 | c.60C>A p.S20= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as COSV100486320; called by muse, mutect2, varscan2
- CYP2C9 | c.117T>A p.I39= | Silent (SNP) | VAF 27/88 reads (31%) | catalogued as COSV99583026; called by muse, mutect2, varscan2
- DNAH10 | c.12561C>T p.N4187= (on ENST00000409039; = p.N4126= on NM_207437.3) | Silent (SNP) | VAF 49/73 reads (67%) | catalogued as COSV101292484; called by muse, mutect2, varscan2
- FCRL3 | c.1938G>T p.L646= | Silent (SNP) | VAF 24/49 reads (49%) | catalogued as COSV100943464; called by muse, mutect2, varscan2
- FOXRED2 | c.1944C>G p.G648= | Silent (SNP) | VAF 11/99 reads (11%) | catalogued as rs1241403791, COSV99341068; called by muse, mutect2, varscan2
- HELQ | c.687C>T p.N229= | Silent (SNP) | VAF 11/61 reads (18%) | catalogued as rs1398024066, COSV99787997; called by muse, mutect2
- INKA1 | c.549C>T p.P183= | Silent (SNP) | VAF 32/41 reads (78%) | catalogued as rs1303148862, COSV100323717; called by muse, mutect2, varscan2
- KLHDC4 | c.1335C>T p.Y445= | Silent (SNP) | VAF 11/64 reads (17%) | catalogued as rs201422258, COSV54506018; called by muse, mutect2, varscan2
- LAMA1 | c.1053T>G p.T351= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as COSV101057265; called by muse, mutect2, varscan2
- LARS1 | c.2856G>A p.L952= (on ENST00000394434 / NM_020117.11; = p.L925= on NM_016460.3) | Silent (SNP) | VAF 24/84 reads (29%) | catalogued as COSV99198716; called by muse, mutect2, varscan2
- LRRC37A3 | c.4485T>G p.A1495= | Silent (SNP) | VAF 178/221 reads (81%) | catalogued as COSV100141367; called by muse, mutect2, varscan2
- MCM10 | c.1035G>A p.T345= (on ENST00000484800 / NM_182751.3; = p.T344= on NM_018518.5) | Silent (SNP) | VAF 18/64 reads (28%) | catalogued as rs779305525, COSV101098365; called by muse, mutect2, varscan2
- MIDEAS | c.2313C>T p.D771= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as COSV99679135; called by muse, mutect2, varscan2
- MTCL1 | c.5520C>A p.P1840= (on ENST00000306329 / NM_001378206.1; = p.P1521= on NM_015210.4) | Silent (SNP) | VAF 39/89 reads (44%) | catalogued as COSV100095092, COSV100095302; called by muse, mutect2, varscan2
- MYH15 | c.2238G>A p.K746= | Silent (SNP) | VAF 8/84 reads (10%) | catalogued as COSV99843986; called by muse, mutect2
- NBN | c.2058G>A p.K686= | Silent (SNP) | VAF 29/66 reads (44%) | catalogued as COSV99619901; called by muse, mutect2, varscan2
- NPFFR2 | c.1551T>A p.T517= | Silent (SNP) | VAF 37/76 reads (49%) | catalogued as COSV100441099; called by muse, mutect2, varscan2
- PCDH7 | c.2775C>A p.P925= | Silent (SNP) | VAF 9/85 reads (11%) | called by muse, mutect2, varscan2
- PHLPP2 | c.2709A>T p.A903= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as COSV100673785; called by muse, mutect2, varscan2
- PLXNA4 | c.5064G>A p.L1688= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as COSV100326151; called by muse, mutect2
- PTPN1 | c.801G>A p.L267= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as COSV100860604; called by muse, mutect2, varscan2
- RBM11 | c.669G>A p.E223= | Silent (SNP) | VAF 23/79 reads (29%) | catalogued as COSV101271228; called by muse, mutect2, varscan2
- SATB2 | c.1800G>A p.A600= | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as rs764410137, COSV53484641; called by muse, mutect2, varscan2
- SCN1A | c.5823G>A p.T1941= (on ENST00000303395 / NM_001202435.3; = p.T1930= on NM_006920.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/45 reads (44%) | catalogued as rs754371368, COSV57672211; ClinVar: likely benign; called by muse, mutect2, varscan2
- TLL1 | c.1500C>T p.V500= | Silent (SNP) | VAF 36/67 reads (54%) | catalogued as COSV99288503; called by muse, mutect2, varscan2
- TSR3 | c.492C>T p.C164= | Silent (SNP) | VAF 18/116 reads (16%) | catalogued as COSV99136091; called by muse, mutect2, varscan2
- YJU2 | c.825C>T p.C275= | Silent (SNP) | VAF 67/105 reads (64%) | catalogued as COSV99508409; called by muse, mutect2, varscan2
- ZFP82 | c.579T>G p.T193= | Silent (SNP) | VAF 21/48 reads (44%) | catalogued as COSV101089243; called by muse, mutect2, varscan2
- ZFYVE9 | c.1005T>C p.S335= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as COSV99820505; called by muse, mutect2, varscan2
- ZNF557 | c.423A>T p.G141= (on ENST00000414706 / NM_001044388.2; = p.G148= on NM_024341.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as COSV99422653; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73852631 G>T | 3'Flank (SNP) | VAF 53/323 reads (16%) | catalogued as rs1303668067; called by muse, mutect2, varscan2
- ETNK2 | c.1015-47C>T | Intron (SNP) | VAF 14/52 reads (27%) | catalogued as COSV100916606; called by muse, mutect2, varscan2
- RBCK1 | c.167+506T>C | Intron (SNP) | VAF 36/72 reads (50%) | catalogued as COSV100675911; called by muse, mutect2, varscan2
- SH2B2 | chr7:102281872 C>T | 5'Flank (SNP) | VAF 13/41 reads (32%) | catalogued as rs1554549356, COSV99476479; called by muse, mutect2, varscan2
